Gene-level copy-number profile of tumor specimen TCGA-73-4666-01A from TCGA case TCGA-73-4666, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 52.2 years (19,074 days).
Specimen TCGA-73-4666-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.68cff7e0-90d6-4918-9aab-90d8e5d0b686.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-73-4666-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/060bbdce-0da8-4605-afc1-179f7949f4a4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 700; copy number 2: 14,663; copy number 3: 23,285; copy number 4: 15,868; copy number 5: 3,341; copy number 7: 23; copy number 8: 793; copy number 9: 1,010; copy number 10: 132.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-73-4666-01A-01D-1204-01): tumor purity 0.45, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,958 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:63,011,463–159,233,377, 1,935 genes, copy number 8–10 (broad region; genes not listed).
- chr11:43,556,436–44,310,139, 23 genes, copy number 7: AC068205.1, MIR670, MIR670HG, AC068205.2, MIR129-2, HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4, AC087521.2, AC087521.4, ALKBH3, SEC14L1P1, ALKBH3-AS1, AC087521.3, C11orf96, AC087521.1, ACCSL, ACCS, AC134775.1, EXT2, ALX4.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
